Surgical pathology report (de-identified scan), TCGA case TCGA-DQ-7590, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Of Michigan, specimen TCGA-DQ-7590-01A (Primary Tumor).

Reg#: [REDACTED] Name [REDACTED] DOB: [REDACTED] Sex [REDACTED] Age: [REDACTED] User Name: [REDACTED]

ACC#	ACC# Number	Order Test Code	Order Test Name	Last Updated
Collected	[REDACTED]	SPF	SP FINAL REPORT	Updated [REDACTED]
SP FINAL REPORT Source:				

HISTORY:

Source of Specimen: Throat. History of left neck mass. Operative Procedure/Tissue Submitted: DL3, possible selective neck dissection.

GROSS:

1. 'Left tonsillar fossa tissue.' Received fresh in a small container for frozen section are seven, tan, soft tissue fragments, ranging from 0.1 to 0.5 cm.
- 1A. Frozen section control. (7ns)
2. 'Deep left tonsillar fossa tissue.' Received fresh in a small container are numerous soft tan-pink tissue fragments, 1.3 x 1.3 x 0.5 cm in aggregate.
- 2A. Frozen section control. (ns)

FROZEN SECTION REPORT

- 1&2. Positive for squamous cell carcinoma. [REDACTED]

I, [REDACTED] have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

MICROSCOPIC DIAGNOSIS:

- 1&2. Left tonsillar fossa and deep left tonsillar fossa, biopsies: Poorly differentiated squamous cell carcinoma (depth of invasion at least 0.6 cm).

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

(electronic signature)

Close

Source: NCI Genomic Data Commons file 8e056953-3a29-4d8f-b866-9dec04901c50 (TCGA-DQ-7590.0A6C6DE2-4BC0-40D5-A775-51C2BBA8846E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).